Gene-level copy-number profile of tumor specimen TCGA-RD-A8MV-01A from TCGA case TCGA-RD-A8MV, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 56.9 years (20,771 days).
Specimen TCGA-RD-A8MV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.3b54d99e-03d1-419f-bc71-8d5a4de68266.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RD-A8MV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9c405adb-66ba-4a02-a843-6152c6970379

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 82; copy number 2: 5,401; copy number 3: 3,958; copy number 4: 29,439; copy number 5: 8,466; copy number 6: 4,591; copy number 7: 3,899; copy number 8: 1,795; copy number 9: 820; copy number 10: 521; copy number 11: 296; copy number 14: 141; copy number 17: 41; copy number 20: 40; copy number 22: 187; copy number 25: 43; copy number 28: 24; copy number 42: 44.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RD-A8MV-01A-11D-A363-01): tumor purity 0.31, ploidy 2.27, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,157 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:164,555,584–173,824,720, 210 genes, copy number 9 (broad region; genes not listed).
- chr4:138,819,954–180,117,163, 554 genes, copy number 10–11 (within-gene range 5–11) (broad region; genes not listed).
- chr6:44,342,650–48,214,794, 53 genes, copy number 9: SPATS1, CDC5L, MIR4642, AL136140.1, AL136140.2, AL133334.1, SUPT3H, NUDT19P4, AL138880.2, RBM22P4, AL138880.1, MIR586, RUNX2, AL096865.1, RUNX2-AS1, CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL451166.1, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1.
- chr6:52,970,650–54,945,099, 49 genes, copy number 9 (within-gene range 3–9): AL121969.1, GSTA4, 7SK, RN7SK, CILK1, AL031178.1, FBXO9, AL031178.2, RN7SL244P, AL512347.1, GCM1, RNU6-464P, SOD1P1, AL512378.1, RNU1-136P, HMGB1P20, ELOVL5, MIR5685, RPS16P5, AL034374.1, RPL31P28, RPL31P33, RPA3P2, AL591034.1, RN7SKP256, NANOGP3, GCLC, AL033397.2, AL033397.1, LINC01564, KLHL31, AL590652.1, LRRC1, AL033384.2, MLIP, AL033384.1, MLIP-AS1, MLIP-IT1, ERHP2, AL359380.1, TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B.
- chr6:75,084,326–80,042,527, 67 genes, copy number 9–11 (within-gene range 3–11) (broad region; genes not listed).
- chr9:20,999,509–23,438,700, 61 genes, copy number 11 (within-gene range 4–11) (broad region; genes not listed).
- chr10:74,744,386–82,987,179, 140 genes, copy number 10–20 (within-gene range 4–20) (broad region; genes not listed).
- chr11:85,452,282–86,952,910, 36 genes, copy number 11 (within-gene range 8–11): AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3, AP003059.1, AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2.
- chr11:89,177,875–90,915,052, 66 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr11:100,336,856–101,872,562, 12 genes, copy number 9 (within-gene range 6–9): RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1.
- chr11:121,361,854–124,159,356, 71 genes, copy number 10 (broad region; genes not listed).
- chr13:31,199,975–51,080,862, 344 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr14:58,646,631–61,751,099, 54 genes, copy number 9 (within-gene range 3–9): LINC01500, AL049873.1, AL049873.2, AKR1B1P5, PPIAP5, DAAM1, GPR135, L3HYPDH, AL121694.1, JKAMP, CCDC175, RTN1, MIR5586, AL133299.1, LRRC9, AL157911.1, PCNX4, DHRS7, SCOCP1, PSMA3P1, RPL17P2, AL157756.1, PPM1A, LINC02322, C14orf39, RBM8B, GNRHR2P1, SALL4P7, SIX6, AL049874.3, AL049874.4, AL049874.2, AL049874.1, SALRNA1, SIX1, SIX4, MNAT1, MAD2L1P1, AL160236.2, SRMP2, TRMT5, AL160236.1, RNU6-398P, SLC38A6, PRKCH, TMEM30B, AL359220.1, AL355916.3, AL355916.2, LINC01303, AL355916.1, HIF1A-AS1, HIF1A, HIF1A-AS3.
- chr15:94,455,469–99,390,729, 87 genes, copy number 25–42 (within-gene range 5–42) (broad region; genes not listed).
- chr20:35,701,347–49,729,842, 353 genes, copy number 9–28 (within-gene range 6–28) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
